Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PP, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PP-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- A. Perinephric fat, excision: Fibroadipose tissue, no tumor seen.
- B. Superior margin, excision: Fibroadipose tissue, no tumor seen.
- C. Base margin, excision: No tumor seen.
- D. Right renal mass, excision: Papillary renal cell carcinoma (chromophil), 3.5cm diameter, Fuhrman nuclear grade 2, excised.
- E. Perinephric fat, excision: No tumor identified.

COMMENT:

Kidney Tumor Synoptic Comment

-Histologic type:

Renal cell carcinoma, papillary (chromophil) type.

-Grade: 2

-Maximum tumor diameter: 3.5 cm.

-Capsule/perirenal fat:

Tumor does not penetrate the capsule which surrounds the tumor completely; only part of this capsule is surrounded by fat or renal tissue.

-Hilar lymph nodes (number positive/number of nodes): None submitted or found.

-Resection margins:

"Superior margin" and "Base margin" are negative for tumor.

-Stage: pT1aNxMx.

ICD-b-3
Carcinoma, papillary
renal cell (chromophil) 8260/3
Site: R Kidney NOS C64.9
JES 3/30/14

[page 2 of 2]
Specimen(s) Received

A:Perinephric fat
B:Superior margin (FS)
C:Base margin (FS)
D:Right renal mass
E:Perinephric fat

Intraoperative Diagnosis

FS1 (B1) "Soft tissue," superior margin, biopsy: Fibroadipose tissue, no tumor.

FS2 (C1) "Kidney," Base margin, biopsy: Renal parenchyma, no tumor.

Clinical History

The patient is a [redacted] year-old man with a right renal mass, who undergoes resection.

Gross Description

The specimen is received in five parts, each labeled with the patient's name and medical record number. Parts A-D are received fresh. Part E is received in formalin.

Part A, additionally labeled "1 - perinephric fat," consists of fatty tissue measuring 1.9 x 1.5 x 1.0 cm as a pile. The specimen is entirely submitted in cassette A1.

Part B, additionally labeled "2 - superior margin," consists of fibrofatty tissue with no visible soft tissue measuring 2.5 x 0.8 x 0.5 cm. The entire specimen is frozen for frozen section 1, with the remnant submitted in cassette B1.

Part C, additionally labeled "3 - base margin (FS)," consists of a single segment of normal-appearing kidney measuring 3.0 x 2.0 x 1.0 cm; it corresponds to a puncture of the renal mass capsule (specimen D). The deep margin is inked blue by the surgeon; it is re-inked black and then entirely submitted for frozen sections 2 and 3 and the tissue blocks are subsequently entirely submitted in cassettes C1-C2.

Part D, additionally labeled "right renal mass," consists of a 3.5 x 2.5 x 2.0 cm nodule that is inked on 50% of the surface. There is attached fat, measuring 4.0 x 3.5 x 2.0 cm as a pile. The nodule is incised to reveal a brown-tan, soft mass that appears to be necrotic. Attached to the nodule is a rim of brown tissue measuring 3.5 x 1.5 x 0.7 cm. Representative sections of the nodule and the attached brown tissue are submitted in cassettes D1-D4. The fatty tissue is thoroughly evaluated for candidate lymph nodes and candidate lymph nodes are submitted in cassette D5. Representative sections of the fat are submitted in cassette D6.

Part E, additionally labeled "5 - perinephric fat," consists of multiple yellow, glistening, irregular, unoriented adipose tissue fragments measuring 14.0 x 8.0 x 2.5 cm in aggregate. Upon sectioning, the specimen consists of grossly normal-appearing adipose tissue without areas of thickening. Representative sections are submitted in cassettes E1-E3.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[redacted] Pathology Resident

[redacted] Pathologist
Electronically signed out on [redacted]

Criteria	lw 1/6/14	Yes	No

Source: NCI Genomic Data Commons file 274f6c8c-8905-4c1d-848d-2f82f681c540 (TCGA-UZ-A9PP.0A596611-ED33-4CC5-9C27-D2F1C5E0E6AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).